Somatic mutation profile of tumor specimen MMRF_2548_1_BM_CD138pos (aliquot MMRF_2548_1_BM_CD138pos_T1_KHS5U_K15216) from MMRF case MMRF_2548, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.4 years (20,959 days).
Specimen MMRF_2548_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1424fac-024b-47c7-8c9e-6ceddb1bd2a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2548_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2548_1_PB_Whole_C3_KHS5U_K15217; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c428c20-71f9-4b5b-9c1e-380d93b8e2c9

The open-access MAF lists 102 somatic variants for this specimen: 43 protein-altering or splice-affecting, 15 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 24, Silent 15, Intron 11, Nonsense Mutation 4, 5'UTR 4, 5'Flank 3, Splice Site 2, Frame Shift Del 2, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- UNC80 | c.5671C>T p.R1891* | Nonsense Mutation (SNP) | VAF 41/74 reads (55%) | catalogued as rs1262654975, COSV55886621; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DAO | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201583577; called by muse, mutect2, varscan2
- EVC2 | c.2360G>A p.R787Q | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.462); catalogued as rs1392104625, COSV100184825; called by muse, mutect2
- GNPDA2 | c.469A>G p.T157A | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); catalogued as rs1267927997, COSV54945947; called by muse, mutect2, varscan2
- IGLV3-19 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 30/31 reads (97%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs540095968; called by muse, mutect2, varscan2
- IL1RAPL1 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.083); catalogued as rs377167082, COSV56279012; called by muse, mutect2, varscan2
- LRP1B | c.5216C>T p.S1739L | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1258906215, COSV67203063; called by muse, mutect2, varscan2
- OR1J4 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.232); catalogued as rs776975075; called by muse, mutect2, varscan2
- OR51Q1 | c.78C>A p.H26Q | Missense Mutation (SNP) | VAF 46/292 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1320943881; called by muse, mutect2, varscan2
- PRUNE2 | c.7331C>A p.A2444D | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.084); catalogued as rs62565560; called by muse, mutect2, varscan2
- PRUNE2 | c.3098G>T p.W1033L | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100944358; called by muse, mutect2, varscan2
- SREBF2 | c.526A>G p.T176A | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs139680630; called by muse, mutect2, varscan2
- TENM3 | c.7468G>A p.A2490T | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1204311486, COSV69314988; called by muse, mutect2
- USH1G | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 106/193 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as rs375077331; called by muse, mutect2, varscan2
- ADCY3 | c.554T>G p.L185R | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- APOL4 | c.49C>T p.Q17* (on ENST00000352371 / NM_145660.2; = p.Q14* on NM_030643.4) | Nonsense Mutation (SNP) | VAF 49/82 reads (60%) | called by muse, mutect2, varscan2
- C19orf44 | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 86/159 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CMYA5 | c.7777T>C p.S2593P | Missense Mutation (SNP) | VAF 76/126 reads (60%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DAB1 | c.952G>T p.V318L (on ENST00000371231; = p.V285L on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/25 reads (96%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYNC2H1 | c.293C>A p.S98* | Nonsense Mutation (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- EPHA5 | c.1320G>T p.E440D | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ESM1 | c.410A>G p.Y137C | Missense Mutation (SNP) | VAF 68/142 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- ETAA1 | c.1998_1999del p.C666* | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | called by pindel, varscan2
- GPR183 | c.697A>C p.T233P | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- HSP90B1 | c.716A>G p.N239S | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- IGKV2-24 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 105/217 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- IL4I1 | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL4R | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); called by muse, mutect2
- KDM1A | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 103/108 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF9 | c.1246A>G p.R416G | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- KMT2C | c.4661-1G>A p.X1554_splice | Splice Site (SNP) | VAF 21/100 reads (21%) | called by muse, mutect2, varscan2
- L3MBTL4 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 70/179 reads (39%) | called by muse, mutect2, varscan2
- MIER1 | c.1048T>C p.Y350H (on ENST00000355356 / NM_001077701.3; = p.Y367H on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/28 reads (96%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MROH1 | c.1733A>C p.H578P | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MYPN | c.3779G>C p.R1260T | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OVCH1 | c.3100G>T p.V1034F | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PDIA3 | c.1365C>A p.F455L | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- PMS2 | c.1400T>C p.V467A | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2
- PTPRQ | c.2077_2080del p.S693Kfs*7 (on ENST00000616559; = p.S651Kfs*7 on NM_001145026.2) | Frame Shift Del (DEL) | VAF 27/41 reads (66%) | called by mutect2, pindel, varscan2
- RD3 | c.297-1G>A p.X99_splice | Splice Site (SNP) | VAF 43/112 reads (38%) | called by muse, mutect2, varscan2
- TIMMDC1 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- TPST1 | c.922C>A p.P308T | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF275 | c.988T>C p.F330L | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRE2 | c.1299C>T p.H433= | Silent (SNP) | VAF 11/143 reads (8%) | called by muse, mutect2
- ATF7IP | c.3015C>T p.P1005= | Silent (SNP) | VAF 10/283 reads (4%) | called by muse, mutect2
- CLDN5 | c.249C>T p.L83= (on ENST00000618236 / NM_001363066.2; = p.L168= on NM_003277.4) | Silent (SNP) | VAF 22/158 reads (14%) | catalogued as rs375234645; called by muse, mutect2, varscan2
- GDNF | c.567G>A p.S189= | Silent (SNP) | VAF 26/307 reads (8%) | catalogued as rs116132124, COSV100427375; called by muse, mutect2
- HDAC6 | c.648C>T p.H216= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs782534324, COSV100491280; called by muse, mutect2, varscan2
- IGLV3-22 | c.136C>T p.L46= | Silent (SNP) | VAF 46/46 reads (100%) | called by muse, varscan2
- IRX4 | c.630G>A p.P210= | Silent (SNP) | VAF 37/187 reads (20%) | catalogued as rs763072295, COSV51471275; called by mutect2, varscan2
- MRPL58 | c.354G>A p.K118= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as rs753997319; called by muse, mutect2, varscan2
- NT5DC2 | c.708C>T p.I236= | Silent (SNP) | VAF 76/166 reads (46%) | catalogued as rs1281077871; called by muse, mutect2, varscan2
- RBM12 | c.1356G>A p.K452= | Silent (SNP) | VAF 12/251 reads (5%) | called by muse, mutect2
- RNF126 | c.711G>A p.A237= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs779853295; called by muse, mutect2, varscan2
- SLFN5 | c.1710G>A p.K570= | Silent (SNP) | VAF 10/264 reads (4%) | called by muse, mutect2
- SULT1C2 | c.312G>A p.R104= | Silent (SNP) | VAF 13/163 reads (8%) | catalogued as rs1468647250; called by muse, mutect2
- TMEM241 | c.729C>T p.A243= | Silent (SNP) | VAF 73/156 reads (47%) | catalogued as COSV101271722; called by muse, mutect2, varscan2
- ZDHHC8 | c.144C>A p.P48= | Silent (SNP) | VAF 73/155 reads (47%) | catalogued as rs370643674; called by muse, mutect2, varscan2
- ABCC12 | c.*159C>T | 3'UTR (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- AC142384.1 | n.1404C>G | RNA (SNP) | VAF 9/146 reads (6%) | called by muse, mutect2
- AMT | c.*755A>C | 3'UTR (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- ARHGEF28 | c.*487G>T | 3'UTR (SNP) | VAF 32/66 reads (48%) | called by muse, mutect2, varscan2
- ARSD | c.*2792G>C | 3'UTR (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- ATP6V0E2 | chr7:149873477 T>G | 5'Flank (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- BDNF | c.-21-15523C>A | Intron (SNP) | VAF 19/155 reads (12%) | called by muse, mutect2, varscan2
- CBLN2 | c.*1065G>A | 3'UTR (SNP) | VAF 33/93 reads (35%) | catalogued as rs1419943978; called by muse, mutect2, varscan2
- CFAP410 | c.*1210G>T | 3'UTR (SNP) | VAF 44/274 reads (16%) | called by muse, varscan2
- CNPY1 | c.*1033C>G | 3'UTR (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- DPYSL2 | c.-47G>A | 5'UTR (SNP) | VAF 3/48 reads (6%) | catalogued as rs1230985423; called by muse, mutect2
- ENPP2 | c.-14G>A | 5'UTR (SNP) | VAF 8/60 reads (13%) | catalogued as rs1398486876; called by muse, mutect2
- FBXO3 | c.1239+1774C>T | Intron (SNP) | VAF 11/147 reads (7%) | called by muse, mutect2
- FSD1L | c.*1206C>T | 3'UTR (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- HEG1 | c.*1726T>C | 3'UTR (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- HGSNAT | c.*826C>T | 3'UTR (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- HLCS | chr21:36749101 G>A | 3'Flank (SNP) | VAF 41/81 reads (51%) | catalogued as rs866698262; called by muse, mutect2, varscan2
- IGLC7 | c.*79C>A | 3'UTR (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- IL20 | c.*86_*88del | 3'UTR (DEL) | VAF 94/374 reads (25%) | called by pindel, varscan2
- IRF2BP2 | c.*1876A>T | 3'UTR (SNP) | VAF 37/103 reads (36%) | called by muse, mutect2, varscan2
- KLHL29 | c.*1789_*1813del | 3'UTR (DEL) | VAF 26/69 reads (38%) | called by mutect2, pindel, varscan2
- MRE11 | c.659+1070G>T | Intron (SNP) | VAF 6/65 reads (9%) | catalogued as rs968691005; called by muse, mutect2
- NCOA7 | c.*2202G>A | 3'UTR (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- NPNT | c.1247-41G>A | Intron (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- PEG3 | c.*1788G>A | 3'UTR (SNP) | VAF 17/262 reads (6%) | called by muse, mutect2
- PLCB1 | c.2524-6161G>A | Intron (SNP) | VAF 21/316 reads (7%) | called by muse, mutect2
- PRSS27 | c.73+87C>G | Intron (SNP) | VAF 10/181 reads (6%) | called by muse, mutect2
- PRTFDC1 | c.*159T>C | 3'UTR (SNP) | VAF 5/84 reads (6%) | catalogued as rs1234890657; called by muse, mutect2
- RAD21 | chr8:116876209 T>C | 5'Flank (SNP) | VAF 3/45 reads (7%) | catalogued as rs1191491009; called by muse, mutect2
- RGS7BP | c.-341C>T | 5'UTR (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2
- RNF130 | c.*24C>G | 3'UTR (SNP) | VAF 14/390 reads (4%) | called by muse, mutect2
- SCG3 | c.*3A>G | 3'UTR (SNP) | VAF 12/316 reads (4%) | called by muse, mutect2
- SLC12A5 | c.2857-71G>A | Intron (SNP) | VAF 17/28 reads (61%) | called by muse, mutect2, varscan2
- SUSD6 | c.*1398G>A | 3'UTR (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- TLE3 | c.1835+118G>A | Intron (SNP) | VAF 18/28 reads (64%) | catalogued as rs942413107; called by muse, mutect2
- TMSB4X | chrX:12975304 G>A | 5'Flank (SNP) | VAF 102/103 reads (99%) | catalogued as COSV66081281; called by muse, mutect2, varscan2
- TMTC3 | c.*488C>A | 3'UTR (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- TRAM1L1 | c.*172G>A | 3'UTR (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- TRIM24 | c.*2759A>G | 3'UTR (SNP) | VAF 15/135 reads (11%) | called by muse, mutect2, varscan2
- UBE2V1 | c.172-129A>C | Intron (SNP) | VAF 19/226 reads (8%) | called by muse, mutect2
- VPS37B | c.111+6896T>C | Intron (SNP) | VAF 89/169 reads (53%) | called by muse, mutect2, varscan2
- VSTM2A | c.634+612T>G | Intron (SNP) | VAF 33/64 reads (52%) | called by muse, mutect2, varscan2
- ZNF148 | c.*4034C>G | 3'UTR (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
- ZNF490 | c.-12G>A | 5'UTR (SNP) | VAF 10/183 reads (5%) | called by muse, mutect2
